Somatic mutation profile of tumor specimen TCGA-HU-A4G9-01A (aliquot TCGA-HU-A4G9-01A-11D-A24D-08) from TCGA case TCGA-HU-A4G9, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,753 days).
Specimen TCGA-HU-A4G9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caec994c-bcdb-4b2f-b679-4e9b8b44b3bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4G9-10A (Blood Derived Normal), aliquot TCGA-HU-A4G9-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0592c38-a9f7-4e46-8076-0d94ba355335

The open-access MAF lists 921 somatic variants for this specimen: 691 protein-altering or splice-affecting, 212 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 454, Silent 212, Frame Shift Del 169, Frame Shift Ins 30, Nonsense Mutation 18, Splice Site 9, Splice Region 7, Intron 7, RNA 6, 5'UTR 4, In Frame Del 4, 3'UTR 1.

Variants (750 of 921; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 62/162 reads (38%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, varscan2
- ARID3A | c.1669A>G p.S557G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs752338179, COSV55043319; called by muse, varscan2
- BRPF1 | c.2794del p.Q932Sfs*5 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs762904815, COSV57403691; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CDAN1 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs80338696, CM023034, COSV62330789; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 20/128 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4447G>A p.G1483R | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs794728223, COSV57309338; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HSD17B4 | c.817C>T p.R273C (on ENST00000414835 / NM_001199291.3; = p.R248C on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs969485098, CM060020, COSV56333485; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.854del p.P285Lfs*21 (on ENST00000642864 / NM_001111125.3; = p.P80Lfs*21 on NM_015075.2) | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs782460038; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 38/84 reads (45%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 45/118 reads (38%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL2 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62929523; called by muse, mutect2, varscan2
- ABCA13 | c.14186G>A p.R4729H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs372286953, COSV68943281; called by muse, mutect2
- ABCA2 | c.4175G>A p.R1392Q (on ENST00000614293; = p.R1362Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs376633527; called by muse, mutect2, varscan2
- ABCB1 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV55945161; called by muse, mutect2, varscan2
- ABCB7 | c.618del p.F206Lfs*12 (on ENST00000373394 / NM_001271696.3; = p.F207Lfs*12 on NM_004299.6) | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs1426619099; called by mutect2, pindel, varscan2
- ABHD10 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.14); catalogued as COSV56324457; called by muse, mutect2, varscan2
- AC105001.2 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.279); catalogued as COSV59108314; called by muse, mutect2, varscan2
- ACACA | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1406135409; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 56/64 reads (88%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA2 | c.1252G>C p.V418L (on ENST00000262607; = p.V177L on NM_177405.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52830269; called by muse, varscan2
- ADAM9 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753966173, COSV65946577; called by muse, mutect2, varscan2
- ADAMTS18 | c.2318G>A p.G773D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51398784; called by muse, mutect2
- ADAMTS8 | c.1893del p.R632Gfs*11 | Frame Shift Del (DEL) | VAF 64/175 reads (37%) | catalogued as COSV99960677; called by mutect2, pindel, varscan2
- ADAMTS9 | c.4190T>C p.L1397P | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55775037; called by muse, mutect2
- ADGRL1 | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61563589; called by muse, mutect2, varscan2
- ADIRF | c.41A>T p.E14V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV64393962; called by muse, mutect2, varscan2
- AEBP1 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as rs1415183456, COSV56255441; called by muse, mutect2, varscan2
- AFAP1L2 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs752318393, COSV58412261; called by muse, mutect2, varscan2
- AK8 | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV53750648; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AL162417.1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs369304227; called by muse, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 37/84 reads (44%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- AMOT | c.2078A>C p.H693P (on ENST00000371959 / NM_001113490.1; = p.H284P on NM_133265.3) | Missense Mutation (SNP) | VAF 136/290 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV59060586; called by muse, mutect2, varscan2
- ANK3 | c.6788C>T p.A2263V | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV55044299; called by muse, mutect2, varscan2
- ANKFY1 | c.3103T>C p.Y1035H (on ENST00000341657 / NM_001330063.2; = p.Y1036H on NM_016376.5) | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58914558; called by muse, mutect2, varscan2
- ANKRD12 | c.6038C>T p.A2013V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs958947092, COSV50819165; called by muse, mutect2, varscan2
- ANKRD44 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56549495; called by muse, mutect2, varscan2
- ANO4 | c.1718C>T p.A573V (on ENST00000392977 / NM_001286615.2; = p.A538V on NM_178826.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1365684188, COSV54585564; called by muse, mutect2, varscan2
- ANO6 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV57656726; called by muse, mutect2, varscan2
- ANXA2 | c.140A>C p.K47T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.123); catalogued as COSV60315516, COSV60318467; called by muse, mutect2, varscan2
- AP3M2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs777884964, COSV51527592; called by muse, mutect2, varscan2
- AP4E1 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199542290, COSV55915041; called by muse, mutect2, varscan2
- APLP2 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53838902; called by muse, mutect2, varscan2
- ARID3C | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758739197, COSV52406349; called by muse, mutect2
- ARMCX1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); catalogued as COSV65704870; called by muse, mutect2, varscan2
- ASIC3 | c.1386+1G>C p.X462_splice | Splice Site (SNP) | VAF 38/93 reads (41%) | catalogued as COSV52520457; called by muse, mutect2, varscan2
- ASXL3 | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV52457386; called by muse, mutect2, varscan2
- ATF3 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV58377137; called by muse, mutect2, varscan2
- ATG2A | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs746013952, COSV65965826; called by muse, mutect2, varscan2
- ATP10A | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63513547; called by muse, mutect2, varscan2
- ATP11B | c.2383A>G p.M795V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1197831062, COSV60026101; called by muse, mutect2, varscan2
- ATP13A1 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs749319067, COSV52282597; called by muse, mutect2, varscan2
- ATP13A1 | c.1463T>C p.V488A | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52282624; called by muse, mutect2, varscan2
- ATP4A | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs898108443, COSV52865537; called by muse, varscan2
- BEX2 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 30/61 reads (49%) | catalogued as COSV65500596; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs370885325, COSV63243887; called by muse, mutect2, varscan2
- BLNK | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199013443, COSV56408891; called by muse, mutect2, varscan2
- BMPR1B | c.76del p.R26Vfs*31 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as COSV99215447; called by mutect2, pindel, varscan2
- BNIP1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs748038701, COSV51569932; called by muse, mutect2, varscan2
- BOD1L1 | c.6565G>A p.D2189N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs200701983; called by muse, mutect2, varscan2
- BRAF | c.1807G>T p.G603C (on ENST00000288602 / NM_001374244.1; = p.G563C on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56070053; called by muse, mutect2, varscan2
- BRD2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66372402; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 36/99 reads (36%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- C16orf92 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs756115752, COSV54226159; called by muse, mutect2, varscan2
- C3AR1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50817478; called by muse, mutect2, varscan2
- C8orf58 | c.879G>A p.K293= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51514426; called by muse, mutect2
- CA3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1236720202, COSV53409207; called by muse, mutect2
- CACNG1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143055819, COSV56826031; called by muse, mutect2, varscan2
- CAGE1 | c.2013C>A p.D671E (on ENST00000512086; = p.D535E on NM_205864.3) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV57074638; called by muse, varscan2
- CAPS2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780956187, COSV60823981; called by muse, mutect2, varscan2
- CARD14 | c.2920G>T p.G974C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs767247623, COSV58338409, COSV58338954; called by muse, mutect2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs770159446; called by mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | catalogued as rs765105588; called by mutect2, varscan2
- CBFA2T3 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745883820, COSV51923194; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | catalogued as rs780649799; called by mutect2, varscan2
- CBX8 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53935438; called by muse, mutect2, varscan2
- CCDC110 | c.1798del p.S600Afs*7 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as COSV56870096; called by mutect2, pindel, varscan2
- CCDC180 | c.2199G>T p.E733D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as COSV63826844; called by mutect2, varscan2
- CCDC40 | c.1445G>A p.C482Y | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs367601192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC8 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs199580829; called by muse, mutect2, varscan2
- CCDC80 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52814950; called by muse, mutect2, varscan2
- CCDC86 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as COSV57124437; called by muse, mutect2, varscan2
- CCDC97 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs569723496, COSV54189473; called by muse, mutect2, varscan2
- CCNF | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs200973445, COSV53537776; called by muse, mutect2, varscan2
- CD1D | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 118/142 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63808407; called by muse, mutect2, varscan2
- CD44 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs147167567; called by muse, mutect2, varscan2
- CD81 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as rs1218622082, COSV55132084; called by muse, mutect2, varscan2
- CDC42BPG | c.4526C>A p.P1509H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV61345440; called by muse, mutect2, varscan2
- CDH16 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs779923317, COSV55334818; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 39/108 reads (36%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDHR4 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58525761; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 10/30 reads (33%) | catalogued as rs375852685; called by mutect2, varscan2
- CEP131 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs373880117, COSV53950511; called by muse, mutect2, varscan2
- CEP350 | c.8117A>G p.N2706S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs765434377, COSV62598758; called by muse, mutect2
- CFH | c.1984A>G p.R662G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs760174473, COSV66405806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGN | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1045284968, COSV54967957, COSV99641820; called by muse, mutect2, varscan2
- CHD1L | c.1550T>C p.I517T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV63612727; called by muse, mutect2, varscan2
- CHD5 | c.4792G>A p.A1598T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.013); catalogued as rs761874883, COSV52407490; called by muse, mutect2, varscan2
- CHD5 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs1195000490, COSV52407278; called by muse, mutect2, varscan2
- CHRDL1 | c.637G>A p.A213T (on ENST00000372045; = p.A219T on NM_145234.4) | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54322790; called by muse, mutect2, varscan2
- CHST4 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs762048757, COSV58296463; called by muse, mutect2, varscan2
- CHSY3 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59271195; called by muse, mutect2, varscan2
- CLTCL1 | c.4595A>G p.H1532R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54225137; called by muse, mutect2, varscan2
- COA7 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV65299105; called by muse, mutect2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 37/77 reads (48%) | catalogued as rs748995811; called by mutect2, varscan2
- COL15A1 | c.3003del p.G1002Afs*15 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs745500795; called by mutect2, pindel, varscan2
- COL16A1 | c.3662A>G p.D1221G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54701142; called by muse, mutect2
- COL17A1 | c.1170del p.E391Kfs*12 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as rs769586532; called by mutect2, pindel, varscan2
- COL18A1 | c.3770del p.P1257Qfs*67 (on ENST00000359759 / NM_130444.3; = p.P1022Qfs*67 on NM_030582.4) | Frame Shift Del (DEL) | VAF 41/111 reads (37%) | catalogued as COSV60594444; called by mutect2, pindel, varscan2
- COL22A1 | c.1758+1G>A p.X586_splice | Splice Site (SNP) | VAF 19/75 reads (25%) | catalogued as rs1215972406, COSV57323207; called by muse, mutect2, varscan2
- COL4A6 | c.4175G>A p.G1392D | Missense Mutation (SNP) | VAF 96/247 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859347; called by muse, mutect2, varscan2
- COL6A3 | c.3218G>A p.S1073N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV55079716; called by muse, mutect2, varscan2
- COL6A3 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758958868, COSV55079736; called by muse, mutect2, varscan2
- COPG1 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV59112356; called by muse, mutect2, varscan2
- CPA4 | c.891del p.K297Nfs*18 | Frame Shift Del (DEL) | VAF 47/178 reads (26%) | catalogued as rs755208608; called by mutect2, pindel, varscan2
- CPNE6 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs922716529, COSV53742517; called by muse, mutect2, varscan2
- CPNE9 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV56067624; called by muse, mutect2, varscan2
- CPSF4 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52853780; called by muse, mutect2, varscan2
- CR1L | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.037); catalogued as COSV65469510; called by muse, mutect2, varscan2
- CR2 | c.1372del p.V458Cfs*22 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV65506091; called by mutect2, pindel, varscan2
- CRACD | c.501del p.K167Nfs*82 | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | catalogued as rs1180697484, COSV99950174; called by mutect2, pindel, varscan2
- CRYBG3 | c.6385T>C p.S2129P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709489; called by muse, mutect2, varscan2
- CSF1R | c.1539C>A p.F513L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV53828527; called by muse, mutect2, varscan2
- CSMD1 | c.4023C>A p.D1341E (on ENST00000520002; = p.D1340E on NM_033225.6) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.71); catalogued as COSV59281935; called by muse, mutect2, varscan2
- CSMD3 | c.9590A>T p.Y3197F (on ENST00000297405 / NM_001363185.1; = p.Y3028F on NM_052900.3) | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.044); catalogued as COSV52103380; called by muse, mutect2, varscan2
- CSMD3 | c.2618T>A p.I873N (on ENST00000297405 / NM_001363185.1; = p.I769N on NM_052900.3) | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52103418; called by muse, mutect2, varscan2
- CSRNP3 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as rs139133187; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 42/164 reads (26%) | catalogued as rs756924682; called by pindel, varscan2*
- CTBP1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52071859; called by muse, mutect2
- CYB5R4 | c.741dup p.E248Rfs*16 | Frame Shift Ins (INS) | VAF 23/50 reads (46%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP20A1 | c.854G>A p.C285Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61908994; called by muse, mutect2, varscan2
- CYP2A6 | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs374200109; called by muse, mutect2, varscan2
- CYP4B1 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV54721134; called by muse, mutect2, varscan2
- CYP4X1 | c.1109G>A p.C370Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64149628, COSV64151467; called by muse, mutect2, varscan2
- CYREN | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780033105, COSV51965564; called by muse, mutect2, varscan2
- DAPK1 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63784201; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DBR1 | c.511T>G p.F171V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV53429012; called by muse, mutect2, varscan2
- DCDC1 | c.4955G>A p.R1652H (on ENST00000597505 / NM_001367979.1; = p.R759H on NM_020869.3) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs374142291, COSV100360782; called by muse, mutect2, varscan2
- DCDC1 | c.4288G>A p.V1430M (on ENST00000597505 / NM_001367979.1; = p.V537M on NM_020869.3) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV100337845; called by muse, mutect2, varscan2
- DCHS1 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763347261, COSV100202649, COSV55030530; called by muse, mutect2, varscan2
- DCLK3 | c.1540T>C p.C514R | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69362191; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX51 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780089893, COSV57957179; called by muse, mutect2, varscan2
- DDX60 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as rs750085737, COSV67095074; called by muse, mutect2, varscan2
- DEPDC1 | c.1018A>G p.K340E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV63957544; called by muse, mutect2, varscan2
- DGAT2L6 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV60717116; called by muse, mutect2, varscan2
- DHX32 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs751987538, COSV52938188; called by muse, mutect2, varscan2
- DIDO1 | c.5234del p.G1745Afs*119 | Frame Shift Del (DEL) | VAF 48/133 reads (36%) | catalogued as COSV99825386; called by mutect2, varscan2
- DKK3 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58867701; called by muse, mutect2, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLGAP4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs529565051, COSV59414419; called by muse, mutect2, varscan2
- DNA2 | c.2326del p.L776Ffs*9 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | catalogued as COSV64428742; called by pindel, varscan2
- DNAH3 | c.9031G>A p.A3011T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs746811682, COSV54500830; called by muse, mutect2, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC13 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV53445668; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.5615A>G p.Q1872R | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV70233443; called by muse, mutect2, varscan2
- DRC1 | c.1164-1G>T p.X388_splice | Splice Site (SNP) | VAF 9/16 reads (56%) | catalogued as COSV56528992, COSV56531411; called by muse, mutect2
- DRD2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571869697, COSV60754213; called by muse, mutect2, varscan2
- DSC3 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV64571714, COSV64572586; called by muse, mutect2, varscan2
- DTL | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65341703; called by muse, mutect2, varscan2
- DUSP29 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765918480, COSV58299987, COSV58301825; called by muse, mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- DYNLL2 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV74093364; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs746509911; called by mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELL | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs142055049; called by muse, mutect2, varscan2
- ELMO3 | c.458G>A p.R153H (on ENST00000652269; = p.R100H on NM_024712.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs754967465, COSV62605870; called by muse, mutect2, varscan2
- ELN | c.891C>T p.G297= | Splice Region (SNP) | VAF 6/148 reads (4%) | catalogued as rs782438247, COSV99332238; called by muse, mutect2
- EML3 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV53881379; called by muse, mutect2, varscan2
- ENPP1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV62929845; called by muse, mutect2, varscan2
- ENTPD2 | c.1400T>C p.L467P (on ENST00000355097 / NM_203468.3; = p.L444P on NM_001246.4) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV57074553; called by muse, mutect2, varscan2
- EOLA2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs781787334, COSV62206947; called by muse, mutect2, varscan2
- EPHB2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs908259906, COSV65859861; called by muse, mutect2, varscan2
- ERAL1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs778235128, COSV54739178, COSV54739854; called by muse, mutect2, varscan2
- ESPL1 | c.5530A>G p.S1844G | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1381678342, COSV54475188; called by muse, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV6 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs750795092, COSV67148171, COSV67148250; called by muse, mutect2, varscan2
- EXOC7 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV58739227; called by muse, mutect2, varscan2
- EXTL3 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.194); catalogued as COSV55036696; called by muse, mutect2, varscan2
- FAAP100 | c.2383G>A p.A795T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.884); catalogued as COSV59883910; called by muse, mutect2, varscan2
- FAM124B | c.397T>G p.C133G | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV66271261; called by muse, mutect2, varscan2
- FAM153B | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs1184696449; called by mutect2, varscan2
- FAM171A1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775763401, COSV65313419; called by muse, mutect2, varscan2
- FAM184A | c.2928G>A p.M976I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV58851648; called by mutect2, varscan2
- FAM193A | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61190907; called by muse, mutect2, varscan2
- FAM43A | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV61672702; called by muse, mutect2, varscan2
- FBLN5 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.215); catalogued as rs774458799, COSV50902096; called by muse, mutect2, varscan2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs772353703; called by mutect2, pindel, varscan2
- FBN3 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV54453421; called by muse, mutect2, varscan2
- FCGBP | c.6602C>T p.A2201V | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.458); catalogued as rs762633802; called by muse, mutect2, varscan2
- FERMT3 | c.1031A>T p.D344V | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); catalogued as COSV54176866; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 38/90 reads (42%) | catalogued as rs144178676; called by mutect2, varscan2
- FGFR3 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs1395484832, COSV99600429; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 48/118 reads (41%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FKBP11 | c.351G>T p.L117F | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56739121; called by muse, mutect2, varscan2
- FN1 | c.6605C>T p.T2202M (on ENST00000359671 / NM_001365524.2; = p.T2171M on NM_002026.4) | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.847); catalogued as rs750419825, COSV60546547; called by muse, mutect2, varscan2
- FN1 | c.5816A>C p.K1939T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as COSV60546564; called by muse, mutect2, varscan2
- FOXD4 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 139/439 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV58698337; called by muse, mutect2, varscan2
- FOXD4L1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV52072854; called by muse, mutect2, varscan2
- FOXP3 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV66050848; called by muse, mutect2, varscan2
- FOXRED1 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as rs755778634, COSV55005151; called by muse, mutect2, varscan2
- FRAS1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs778397090, COSV53589239; called by muse, mutect2, varscan2
- FRMPD2 | c.27C>T p.G9= | Splice Region (SNP) | VAF 26/83 reads (31%) | catalogued as rs1261587365, COSV59715158; called by muse, mutect2, varscan2
- FSCB | c.1852G>C p.A618P | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV61216519, COSV61216543; called by muse, varscan2
- FTCD | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV52423167, COSV52427684; called by muse, mutect2, varscan2
- FZD6 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV62470594; called by muse, mutect2, varscan2
- FZD8 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65967496; called by muse, mutect2, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs777471402; called by mutect2, pindel, varscan2
- GBA | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59168954; called by muse, mutect2, varscan2
- GDE1 | c.904A>G p.N302D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54900911; called by muse, mutect2, varscan2
- GGA1 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV57328878; called by muse, mutect2, varscan2
- GMPS | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55807722, COSV55807905, COSV99902842; called by muse, mutect2, varscan2
- GNAZ | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50736921; called by muse, mutect2, varscan2
- GP5 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59877665; called by muse, mutect2, varscan2
- GPHN | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1322719524, COSV59473055; called by muse, mutect2, varscan2
- GPR135 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761846343, COSV67749444; called by muse, mutect2, varscan2
- GPRC5B | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs565486943, COSV56025109; called by muse, mutect2, varscan2
- GRIN2D | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs201028602, COSV54376967; called by muse, mutect2, varscan2
- GRK1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936018736, COSV59551630; called by muse, mutect2, varscan2
- GYS2 | c.1209del p.K403Nfs*7 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs777954647, COSV53922451; called by mutect2, pindel, varscan2
- HDAC4 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs868676793, COSV61859359; called by muse, mutect2, varscan2
- HECA | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62768477; called by muse, mutect2, varscan2
- HECTD1 | c.5000G>A p.R1667H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs371260055, COSV101237541; called by muse, mutect2, varscan2
- HECTD4 | c.4592A>C p.D1531A | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV66386702; called by muse, mutect2, varscan2
- HERPUD2 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV60943850; called by muse, mutect2, varscan2
- HGFAC | c.568del p.R190Gfs*57 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1560192016; called by mutect2, pindel
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs761272507; called by mutect2, varscan2
- HSPA6 | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV59059935; called by muse, mutect2, varscan2
- HTR3D | c.1291G>A p.A431T (on ENST00000382489 / NM_001163646.2; = p.A256T on NM_182537.3) | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775928291, COSV61913275; called by muse, mutect2, varscan2
- HTT | c.5021C>T p.S1674L | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs753577443, COSV61857410; called by muse, mutect2, varscan2
- IDH2 | c.435dup p.T146Dfs*126 | Frame Shift Ins (INS) | VAF 26/72 reads (36%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, varscan2
- IDI1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs776566959, COSV67281399; called by muse, mutect2, varscan2
- IGFN1 | c.1865G>A p.S622N (on ENST00000295591 / NM_001367841.1; = p.S3079N on NM_001164586.2) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV55166000; called by muse, mutect2, varscan2
- IGHG3 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs370664311; called by muse, mutect2, varscan2
- IGLC3 | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | PolyPhen possibly damaging (0.905); catalogued as rs555279361; called by muse, mutect2, varscan2
- IGLV10-54 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as rs546300761, COSV101135411; called by muse, mutect2, varscan2
- IL12RB2 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV52020269; called by muse, mutect2, varscan2
- IL13 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs200168712, COSV100449402; called by muse, mutect2, varscan2
- IL17RD | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs751884613, COSV56335040; called by muse, mutect2, varscan2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- IL32 | c.490C>T p.R164W (on ENST00000396890 / NM_001308078.4; = p.R118W on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as rs371460714, COSV99145454; called by muse, mutect2, varscan2
- IQCE | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs767810121, COSV58076491; called by muse, mutect2, varscan2
- ITGB4 | c.5443A>G p.M1815V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1487725912, COSV52321903; called by muse, varscan2
- ITIH4 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs569565296, COSV56571346; called by muse, mutect2, varscan2
- ITIH6 | c.3745G>A p.A1249T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV54486488; called by muse, mutect2, varscan2
- ITK | c.1048G>T p.G350W | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV70060401; called by muse, mutect2, varscan2
- JADE1 | c.625T>C p.C209R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56904254; called by muse, mutect2, varscan2
- JMJD6 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as COSV58300416; called by muse, mutect2, varscan2
- KALRN | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53753026; called by muse, mutect2, varscan2
- KAT6B | c.5869C>T p.R1957W | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1215579099, COSV54742102; called by muse, mutect2, varscan2
- KCNJ9 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV63631440; called by muse, mutect2, varscan2
- KCNQ5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs920140431, COSV59649400, COSV59676282; called by muse, mutect2, varscan2
- KCTD18 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1280918522, COSV63343925; called by muse, mutect2, varscan2
- KIAA2026 | c.5706A>C p.Q1902H | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV67353326; called by muse, mutect2, varscan2
- KIF5B | c.2438del p.K813Rfs*62 | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | catalogued as COSV56655781; called by mutect2, pindel, varscan2
- KIT | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV55388771, COSV55404917; called by muse, mutect2, varscan2
- KLHDC7A | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68768977; called by muse, mutect2, varscan2
- KLK5 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs906197652, COSV60449517; called by muse, mutect2, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KNG1 | c.982T>C p.C328R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398971331, COSV53976059; called by muse, mutect2, varscan2
- KRTAP10-10 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59951828; called by muse, mutect2, varscan2
- LAMA5 | c.10012C>T p.R3338* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs150238261, COSV53352963; called by muse, mutect2, varscan2
- LAMB1 | c.1371T>C p.S457= | Splice Region (SNP) | VAF 19/41 reads (46%) | catalogued as COSV55961575; called by muse, mutect2
- LAMC3 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs370174192, COSV63088572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LBX1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64621476; called by muse, mutect2, varscan2
- LCE1D | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | PolyPhen possibly damaging (0.659); catalogued as rs1468360393, COSV58270476; called by muse, mutect2, varscan2
- LCK | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as rs139649211; called by muse, mutect2, varscan2
- LEF1 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV54463452; called by muse, mutect2, varscan2
- LGR6 | c.1775del p.V592Afs*10 (on ENST00000367278 / NM_001017403.1; = p.V540Afs*10 on NM_021636.3) | Frame Shift Del (DEL) | VAF 45/138 reads (33%) | catalogued as rs113146160, COSV55152990; called by mutect2, pindel, varscan2
- LHX5 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV55661746; called by muse, mutect2, varscan2
- LINS1 | c.1547C>A p.S516* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59077886; called by muse, mutect2, varscan2
- LMNA | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs59601651, COSV61541978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LONP2 | c.898del p.M300Cfs*10 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs745798174, COSV99035475; called by mutect2, pindel, varscan2
- LRIG1 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1425611577, COSV56236723; called by muse, mutect2, varscan2
- LRRC24 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV52877697; called by muse, mutect2, varscan2
- LRRC31 | c.254del p.K85Rfs*7 | Frame Shift Del (DEL) | VAF 55/213 reads (26%) | catalogued as rs34511323; called by mutect2, pindel, varscan2
- LSG1 | c.1600T>C p.Y534H | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV54568515; called by muse, mutect2, varscan2
- LTBP1 | c.4517G>A p.C1506Y (on ENST00000404816 / NM_206943.4; = p.C1180Y on NM_000627.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55375523; called by muse, mutect2, varscan2
- LTBP1 | c.4699dup p.L1567Pfs*6 (on ENST00000404816 / NM_206943.4; = p.L1241Pfs*6 on NM_000627.4) | Frame Shift Ins (INS) | VAF 31/68 reads (46%) | catalogued as rs1303632187; called by mutect2, pindel, varscan2
- LY6E | c.172+1G>A p.X58_splice | Splice Site (SNP) | VAF 25/140 reads (18%) | catalogued as COSV52869476; called by muse, mutect2, varscan2
- MAB21L2 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58260804; called by muse, mutect2, varscan2
- MAGEB6 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV100983666, COSV66872362; called by muse, mutect2, varscan2
- MAK16 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs201156037, COSV100789452; called by muse, mutect2, varscan2
- MANBA | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56962900, COSV99898580; called by muse, mutect2, varscan2
- MANEA | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV62589246; called by muse, mutect2, varscan2
- MANEA | c.517A>G p.M173V | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs1445625612, COSV62589255; called by muse, mutect2, varscan2
- MAP3K3 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51991149; called by muse, mutect2, varscan2
- MAP3K6 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.896); catalogued as COSV54640488; called by muse, mutect2, varscan2
- MARF1 | c.3899A>G p.Y1300C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV60019888; called by muse, mutect2, varscan2
- MARVELD2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1313802557, COSV57779494; called by muse, mutect2, varscan2
- MBD3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV50082996; called by muse, mutect2
- MCM2 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs766565920, COSV54032012; called by muse, mutect2
- MCTP2 | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV63291634, COSV63293134; called by muse, mutect2, varscan2
- MEAK7 | c.529+2C>T p.X177_splice | Splice Site (SNP) | VAF 18/48 reads (38%) | catalogued as rs1233775326, COSV59143153; called by mutect2, varscan2
- MEAK7 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV59143163; called by muse, mutect2, varscan2
- MED12L | c.1011del p.G338Afs*4 | Frame Shift Del (DEL) | VAF 89/306 reads (29%) | catalogued as COSV56379857; called by mutect2, pindel, varscan2
- MED14 | c.2162T>C p.V721A | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV61355852; called by muse, mutect2, varscan2
- MEGF8 | c.3343A>G p.N1115D (on ENST00000251268 / NM_001271938.2; = p.N1048D on NM_001410.3) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.253); catalogued as COSV52075116; called by muse, mutect2, varscan2
- MMD2 | c.619G>A p.E207K (on ENST00000404774 / NM_001100600.2; = p.E183K on NM_198403.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as rs763891418, COSV68659716; called by muse, mutect2, varscan2
- MMP12 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs189745605, COSV58259042; called by muse, mutect2, varscan2
- MMRN1 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs368250909, COSV53333695; called by muse, mutect2, varscan2
- MMUT | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.374); catalogued as COSV51272327; called by muse, mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs753079987; called by mutect2, varscan2
- MSH4 | c.1663T>C p.S555P | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV54196617; called by muse, mutect2, varscan2
- MST1R | c.3353-2A>G p.X1118_splice | Splice Site (SNP) | VAF 35/153 reads (23%) | catalogued as COSV56564503; called by muse, mutect2, varscan2
- MTHFSD | c.1004G>A p.R335Q (on ENST00000360900 / NM_001159377.2; = p.R334Q on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as rs758667404, COSV59802196; called by muse, mutect2, varscan2
- MTTP | c.2584G>A p.V862I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs760443132, COSV55503765; called by muse, mutect2, varscan2
- MUC16 | c.25658C>A p.P8553H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); catalogued as COSV67444917, COSV67488259; called by muse, mutect2, varscan2
- MYBL2 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.249); catalogued as COSV53827534; called by muse, mutect2
- MYH14 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs370936318; called by muse, mutect2, varscan2
- MYH9 | c.2408A>G p.Q803R | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.119); catalogued as COSV53381964; called by muse, varscan2
- MYLK | c.3916G>A p.G1306S | Missense Mutation (SNP) | VAF 130/479 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs755117377, COSV60604781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV52751757; called by muse, mutect2, varscan2
- MYO15A | c.7786A>G p.R2596G | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs886052677, COSV52751766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.3962C>T p.A1321V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1341987583, COSV62745417; called by muse, mutect2, varscan2
- MYO1C | c.1400C>T p.A467V (on ENST00000648651 / NM_001080779.2; = p.A432V on NM_033375.5) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs778512232, COSV62998333; called by muse, mutect2
- MYO1F | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs201646155, COSV57791852; called by muse, mutect2, varscan2
- MYO5B | c.3988G>A p.G1330S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.102); catalogued as rs557902503, COSV53211266; called by muse, mutect2, varscan2
- MYOD1 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV51452621; called by muse, mutect2, varscan2
- MYOZ3 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs146765925; called by muse, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs763929397; called by mutect2, varscan2
- NADK | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV58269097; called by muse, mutect2, varscan2
- NBR1 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV57830804; called by muse, mutect2, varscan2
- NCAPD2 | c.3941C>A p.P1314Q | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57520423; called by muse, mutect2, varscan2
- NCKAP5 | c.4231C>T p.R1411C | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs200882141, COSV58427315; called by muse, mutect2, varscan2
- NCOR1 | c.4667C>T p.A1556V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV51961055; called by muse, mutect2, varscan2
- NEB | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); catalogued as COSV50810339; called by muse, mutect2, varscan2
- NKX2-8 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177558428, COSV51873037; called by muse, mutect2, varscan2
- NLRC3 | c.1259T>G p.M420R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV57087108; called by muse, mutect2, varscan2
- NLRP3 | c.1556T>A p.I519N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV60220014; called by muse, mutect2, varscan2
- NLRP9 | c.2329A>G p.M777V | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60459576; called by muse, mutect2, varscan2
- NME3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs189034490; called by muse, mutect2, varscan2
- NMUR1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59403455; called by muse, mutect2, varscan2
- NOL6 | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397385880, COSV53039201; called by muse, mutect2, varscan2
- NOS1 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs757597537, COSV57606703; called by muse, mutect2, varscan2
- NPAP1 | c.317del p.P106Rfs*9 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs762821502; called by mutect2, pindel, varscan2
- NPM2 | c.268A>G p.M90V | Missense Mutation (SNP) | VAF 82/396 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775998097, COSV57075124; called by muse, mutect2, varscan2
- NRG1 | c.1541C>T p.A514V (on ENST00000405005 / NM_013964.5; = p.A519V on NM_013956.5) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV55148518; called by muse, mutect2, varscan2
- NSMAF | c.1597C>A p.L533M | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV50683816; called by muse, mutect2, varscan2
- NUCB1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54385066; called by muse, mutect2, varscan2
- NUP133 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54568234; called by muse, mutect2, varscan2
- NUP205 | c.5261A>G p.Q1754R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.444); catalogued as COSV53654983, COSV53663807; called by muse, mutect2, varscan2
- NUP210 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV54402324; called by muse, mutect2, varscan2
- NYX | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV61180241; called by muse, mutect2, varscan2
- OGDHL | c.2375A>C p.D792A | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65100773; called by muse, mutect2, varscan2
- OR11H4 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV59559753; called by muse, mutect2, varscan2
- OR2M5 | c.649T>C p.S217P | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63545707; called by muse, varscan2
- OR4D9 | c.326del p.G109Efs*9 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | catalogued as rs759093140, COSV100259719; called by mutect2, pindel, varscan2
- OR56B4 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV57203750; called by muse, mutect2, varscan2
- OR5L2 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65723370; called by muse, mutect2, varscan2
- P2RX2 | c.680C>T p.T227M (on ENST00000343948 / NM_170683.4; = p.T155M on NM_012226.5) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs1187819303, COSV57674228; called by muse, mutect2, varscan2
- PABPN1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1421864106, COSV53729079, COSV53729967; called by muse, mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel, varscan2
- PAQR9 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV61417577; called by muse, mutect2, varscan2
- PCBP2 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63727936; called by muse, mutect2, varscan2
- PCDH7 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV62336522; called by muse, mutect2
- PCDHA7 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.417); catalogued as COSV65341833; called by muse, mutect2, varscan2
- PCK1 | c.1833_1834dup p.I612Rfs*5 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | catalogued as rs1489385207; called by mutect2, varscan2
- PCLO | c.11030G>A p.R3677H | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139066156, COSV61616280; called by muse, mutect2, varscan2
- PDCD6IP | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs560771018, COSV56241188; called by muse, mutect2, varscan2
- PDE4DIP | c.4112T>C p.V1371A | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV57674888; called by muse, mutect2, varscan2
- PDGFRB | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.812); catalogued as rs1190335517, COSV55800972; called by muse, mutect2, varscan2
- PDIA5 | c.58T>C p.W20R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV60247115; called by muse, mutect2, varscan2
- PDS5B | c.2170dup p.R724Pfs*16 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs746601412; called by mutect2, varscan2
- PDZD2 | c.308dup p.K104Qfs*38 | Frame Shift Ins (INS) | VAF 30/104 reads (29%) | catalogued as rs750970663; called by mutect2, varscan2
- PEG3 | c.4663G>A p.G1555S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV55624721, COSV99687379; called by muse, mutect2, varscan2
- PELP1 | c.3299del p.K1100Rfs*43 | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | catalogued as COSV52591823; called by mutect2, pindel, varscan2
- PEX1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771535312, COSV50394612; called by muse, mutect2, varscan2
- PHEX | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65073747; called by muse, mutect2, varscan2
- PHKG2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs756345604, COSV60310988, COSV60312048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PICK1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57634519; called by muse, mutect2, varscan2
- PIK3C2B | c.4385C>T p.P1462L | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs1269267839, COSV65809018; called by muse, mutect2, varscan2
- PKHD1L1 | c.7990A>G p.N2664D | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV65737095; called by muse, mutect2, varscan2
- PKP1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV55819843; called by muse, mutect2, varscan2
- PKP2 | c.775_777del p.E259del | In Frame Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs1169387259; called by mutect2, pindel, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 54/151 reads (36%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCG1 | c.3130+2T>C p.X1044_splice | Splice Site (SNP) | VAF 18/36 reads (50%) | catalogued as COSV54815237; called by muse, mutect2, varscan2
- PLEC | c.12911C>T p.T4304M (on ENST00000322810 / NM_201380.4; = p.T4194M on NM_000445.5) | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782411778, COSV59603535; called by muse, mutect2, varscan2
- PLXNA2 | c.908C>G p.A303G | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV65437642, COSV65445371; called by muse, mutect2, varscan2
- PML | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); catalogued as rs1468020613, COSV51442050; called by muse, mutect2, varscan2
- PMS2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs587782602, COSV56219620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNISR | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV65078640; called by muse, mutect2, varscan2
- PNISR | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768710587, COSV65078651; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POU4F3 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV57942340; called by muse, mutect2, varscan2
- PPAT | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51702986; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 51/129 reads (40%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PPP1R9A | c.1192C>T p.H398Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.558); catalogued as COSV56881420, COSV56906964; called by muse, mutect2
- PPP2R5D | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs779909900, COSV57839103; called by muse, mutect2, varscan2
- PPP6R3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs1269688410, COSV55721422; called by muse, mutect2, varscan2
- PRAG1 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs368352329; called by muse, mutect2, varscan2
- PRAM1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV55311808; called by muse, mutect2, varscan2
- PRDM13 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.538); catalogued as COSV65028836; called by muse, mutect2, varscan2
- PRDM5 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs373822101; called by muse, mutect2, varscan2
- PREB | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV53204493; called by muse, mutect2, varscan2
- PRF1 | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64614406; called by muse, mutect2, varscan2
- PRKACB | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs1429099607, CM157396, COSV65758829; called by muse, mutect2, varscan2
- PRKCE | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs772347149, COSV60312579; called by muse, mutect2, varscan2
- PRR12 | c.1571del p.G524Afs*26 (on ENST00000615927; = p.G1345Afs*26 on NM_020719.3) | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as COSV69820475; called by mutect2, varscan2
- PRR19 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs985189519, COSV56623790; called by muse, mutect2, varscan2
- PSD | c.958A>G p.S320G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs774151281, COSV50041766; called by muse, mutect2, varscan2
- PSKH2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs754554109, COSV52609191, COSV52609532; called by muse, mutect2, varscan2
- PTBP2 | c.1101C>T p.F367= (on ENST00000426398 / NM_001300986.2; = p.F359= on NM_021190.4) | Splice Region (SNP) | VAF 42/107 reads (39%) | catalogued as COSV64623283; called by muse, mutect2, varscan2
- PTCHD3 | c.1764del p.F588Lfs*18 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs1448522271; called by mutect2, pindel, varscan2
- PTH1R | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs148778122; called by muse, mutect2, varscan2
- PTPRJ | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs536396969, COSV69249788; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PTPRU | c.3258C>T p.S1086= | Splice Region (SNP) | VAF 32/88 reads (36%) | catalogued as rs771446818, COSV60521833; called by muse, mutect2, varscan2
- PUM2 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs1434706523, COSV57577787; called by muse, mutect2, varscan2
- PUM2 | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as COSV57577796; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | catalogued as rs1234606471; called by mutect2, pindel, varscan2
- PXK | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373843935; called by muse, mutect2, varscan2
- QKI | c.401dup p.E135Gfs*5 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | catalogued as rs755727862; called by mutect2, varscan2
- RAI1 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1363856805, COSV55389038; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RASGEF1A | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65666641; called by muse, mutect2, varscan2
- RBM19 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs201979395; called by muse, mutect2, varscan2
- RBM19 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV55688155; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 25/48 reads (52%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM33 | c.621A>T p.E207D | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs768319432, COSV55295467; called by muse, mutect2, varscan2
- RCVRN | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs754840876, COSV56840987; called by muse, mutect2, varscan2
- RECK | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs141528795; called by muse, mutect2, varscan2
- REG3G | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV55448268; called by muse, mutect2, varscan2
- RELN | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs375141725; called by muse, mutect2, varscan2
- RFX5 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV51837996; called by muse, mutect2, varscan2
- RGS9 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs201964792, COSV52223080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHBDD2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs928236647, COSV50086731; called by muse, mutect2, varscan2
- RIMKLB | c.1106del p.G369Afs*5 | Frame Shift Del (DEL) | VAF 62/198 reads (31%) | catalogued as COSV104409540; called by mutect2, pindel, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs745408248; called by mutect2, varscan2
- RNASEH2A | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV55551202; called by muse, mutect2, varscan2
- RNF113B | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV57434225; called by muse, mutect2, varscan2
- RNF138 | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55233295; called by muse, mutect2, varscan2
- RNF220 | c.74T>G p.L25R | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62404740; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 139/225 reads (62%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO2 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs756826211, COSV59896927; called by muse, mutect2, varscan2
- RP1L1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs370720560; called by muse, mutect2
- RPGRIP1L | c.1383A>C p.E461D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1218959399, COSV50902692; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP40 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100123891; called by muse, mutect2
- RPS6KL1 | c.1174T>C p.W392R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63580665; called by muse, mutect2, varscan2
- RREB1 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.998); catalogued as rs1451274258, COSV58553424; called by muse, mutect2, varscan2
- RTN1 | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143124571; called by muse, mutect2, varscan2
- S1PR4 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as rs369301655, COSV55739549; called by muse, mutect2, varscan2
- SALL4 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV53849816; called by muse, mutect2, varscan2
- SAMHD1 | c.1660C>A p.P554T (on ENST00000262878 / NM_001363729.2; = p.P589T on NM_015474.4) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53428256; called by muse, mutect2, varscan2
- SARS1 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52319536; called by muse, mutect2, varscan2
- SBF1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); catalogued as rs146850293; called by muse, mutect2, varscan2
- SCN4A | c.4535G>A p.G1512D | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV71125598; called by muse, mutect2, varscan2
- SCN4A | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767603831, COSV71125599, COSV71125730; called by muse, mutect2
- SCUBE1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV51808469; called by muse, mutect2, varscan2
- SDR39U1 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52158709; called by muse, mutect2, varscan2
- SEC24C | c.1375dup p.Q459Pfs*17 | Frame Shift Ins (INS) | VAF 39/133 reads (29%) | catalogued as rs764652839; called by mutect2, varscan2
- SEMA4A | c.1999A>G p.R667G | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61772014; called by muse, mutect2, varscan2
- SEMA6D | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV60372844; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs750651342; called by mutect2, varscan2
- SGCA | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV56248317; called by muse, mutect2, varscan2
- SGCE | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.207); catalogued as rs1458308050, COSV56015591; called by muse, mutect2
- SHANK2 | c.3952A>G p.T1318A | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV53585714; called by muse, mutect2
- SHANK2 | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV53585743; called by muse, mutect2, varscan2
- SHROOM1 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100166944; called by muse, mutect2
- SIN3A | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV64581720; called by muse, mutect2, varscan2
- SLC18A3 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV60320216; called by muse, mutect2, varscan2
- SLC25A14 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54416893, COSV99502757; called by muse, mutect2, varscan2
- SLC2A2 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV58584527; called by muse, mutect2, varscan2
- SLC2A5 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1055752925, COSV66235528; called by muse, mutect2, varscan2
- SLC32A1 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54145679; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 63/109 reads (58%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC45A4 | c.2224G>A p.G742R (on ENST00000517878 / NM_001286646.2; = p.G691R on NM_001080431.2) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as rs763918785, COSV50133014; called by muse, mutect2, varscan2
- SLC52A2 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV57350709; called by muse, mutect2, varscan2
- SLC6A7 | c.832del p.Q278Sfs*82 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | catalogued as COSV57939345; called by mutect2, pindel, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLC8A2 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV52637664; called by muse, mutect2, varscan2
- SLC9A4 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376409344; called by muse, mutect2, varscan2
- SLCO4C1 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs770439268, COSV60512783; called by muse, mutect2, varscan2
- SLITRK5 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.121); catalogued as COSV61520983; called by muse, mutect2, varscan2
- SLX4 | c.2347G>A p.V783I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.29); catalogued as rs771580450, COSV53560884; ClinVar: uncertain significance; called by muse, mutect2
- SMC1A | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59127699; called by muse, mutect2, varscan2
- SMG1 | c.8179C>T p.R2727C | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776873619, COSV67169507; called by muse, mutect2, varscan2
- SNAPC1 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV53519168; called by muse, mutect2, varscan2
- SNAPC4 | c.3878G>A p.R1293H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs777312856, COSV53730710; called by muse, mutect2, varscan2
- SOHLH2 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58520729; called by muse, varscan2
- SON | c.4136C>T p.S1379L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs906057051, COSV51650647; called by muse, mutect2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SORL1 | c.4706G>A p.G1569E | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52749313; called by muse, mutect2, varscan2
- SOX17 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52024304; called by muse, mutect2
- SOX17 | c.983del p.P328Rfs*59 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs1170462661; called by mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 28/34 reads (82%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATC1 | c.274A>C p.M92L | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66298041; called by muse, mutect2, varscan2
- SPTBN1 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs1558446045, COSV61685552; called by muse, mutect2, varscan2
- SPTLC3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs375500511, COSV65463690; called by muse, mutect2, varscan2
- ST6GAL2 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 59/104 reads (57%) | PolyPhen possibly damaging (0.849); catalogued as rs772145681, COSV62415863; called by muse, mutect2, varscan2
- STARD8 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52921843; called by muse, mutect2, varscan2
- STAT2 | c.1467dup p.K490Qfs*41 | Frame Shift Ins (INS) | VAF 33/95 reads (35%) | catalogued as rs763294380; called by mutect2, varscan2
- STRIP1 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs1264616896, COSV63929707; called by muse, mutect2, varscan2
- STYXL2 | c.2560T>C p.Y854H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54802022; called by muse, mutect2, varscan2
- SULF1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52673329, COSV99484608; called by muse, varscan2
- SULF1 | c.345del p.S116Rfs*47 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | catalogued as COSV52676860; called by pindel, varscan2
- SUMO3 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60537704; called by muse, mutect2, varscan2
- SWAP70 | c.305del p.N102Tfs*31 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | catalogued as rs749995893; called by mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYNGR4 | c.679dup p.R227Pfs*7 | Frame Shift Ins (INS) | VAF 22/71 reads (31%) | catalogued as rs1434458579; called by mutect2, pindel, varscan2
- SYTL1 | c.1109C>T p.P370L (on ENST00000543823; = p.P358L on NM_032872.3) | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV58870120; called by muse, mutect2, varscan2
- SYTL4 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52165391, COSV99343165; called by muse, mutect2, varscan2
- TAS2R14 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs772125764, COSV67852245; called by muse, mutect2, varscan2
- TATDN1 | c.882dup p.P295Sfs*24 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | catalogued as rs771945528; called by mutect2, pindel, varscan2
- TBC1D10C | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV56701869; called by muse, mutect2, varscan2
- TBC1D22A | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs749679165, COSV61435540; called by muse, mutect2, varscan2
- TBC1D9 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs763242846, COSV71306864; called by muse, mutect2, varscan2
- TBX21 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769911299, COSV51595004; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 71/226 reads (31%) | catalogued as rs763321097; called by mutect2, varscan2
- TECTA | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV50687988; called by muse, mutect2, varscan2
- TEK | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757379347, COSV66227449; called by muse, mutect2, varscan2
- TENM3 | c.6748del p.Y2250Mfs*4 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as COSV101305550; called by mutect2, pindel, varscan2
- TESK1 | c.220-2A>G p.X74_splice | Splice Site (SNP) | VAF 25/55 reads (45%) | catalogued as COSV52410179; called by muse, mutect2, varscan2
- TET3 | c.3425T>C p.L1142P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69640683; called by muse, mutect2, varscan2
- TIAM2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59689531; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TIMP3 | c.602dup p.D202Gfs*2 | Frame Shift Ins (INS) | VAF 16/38 reads (42%) | catalogued as rs749890843; called by mutect2, varscan2
- TIPARP | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs17854621, COSV55813223; called by muse, mutect2, varscan2
- TLX3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV51538915; called by muse, mutect2
- TMEM163 | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV56103485; called by muse, mutect2, varscan2
- TMEM183A | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 49/166 reads (30%) | catalogued as rs1558048355, COSV100923261; called by muse, mutect2, varscan2
- TMEM255B | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs778415708, COSV64711450; called by muse, mutect2, varscan2
- TMEM39B | c.874A>G p.S292G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs926571528, COSV60377410; called by muse, mutect2, varscan2
- TNFAIP2 | c.1391C>T p.T464I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs760096089, COSV60693792; called by muse, mutect2, varscan2
- TNFRSF10C | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs753883363, COSV63511275; called by muse, varscan2
- TNKS2 | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs764051162, COSV65414656; called by muse, mutect2, varscan2
- TNKS2 | c.3092A>G p.H1031R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171286209, COSV65414661; called by muse, mutect2, varscan2
- TONSL | c.3647G>T p.G1216V | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV52870949, COSV99465684; called by muse, mutect2, varscan2
- TP53INP2 | c.48del p.E17Kfs*50 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs758602096; called by mutect2, varscan2
- TRANK1 | c.7973G>A p.R2658Q | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV57140441; called by muse, mutect2, varscan2
- TRAPPC12 | c.1775A>G p.Q592R | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1408707837, COSV60845187; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIT1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs764506732, COSV57547108; called by muse, mutect2, varscan2
- TRPV6 | c.1777T>G p.F593V | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as COSV63890508; called by muse, mutect2, varscan2
- TRRAP | c.6334A>G p.T2112A (on ENST00000359863 / NM_001244580.1; = p.T2094A on NM_003496.3) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV62838936; called by muse, mutect2, varscan2
- TSHZ3 | c.1446C>G p.D482E | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs745403920, COSV53664438, COSV53666789; called by muse, mutect2, varscan2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | catalogued as rs764514103; called by mutect2, pindel, varscan2
- TTBK1 | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs377414505; called by muse, mutect2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs756650873; called by mutect2, varscan2
- TTK | c.2560_2561del p.R854Gfs*10 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as COSV57883906; called by pindel, varscan2
- TUBGCP6 | c.4009G>A p.G1337R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs751773877, COSV50536565; called by muse, mutect2, varscan2
- UBE3B | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs749323192, COSV55091208; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 82/175 reads (47%) | catalogued as rs763652408; called by mutect2, varscan2
- UGGT2 | c.3683A>G p.K1228R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1463760552, COSV65072336; called by muse, mutect2, varscan2
- UNC13B | c.3799C>T p.R1267W | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141208447; called by muse, mutect2, varscan2
- UPF3B | c.566del p.N189Ifs*4 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as COSV52230474; called by mutect2, pindel, varscan2
- USH2A | c.1145T>G p.V382G | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56327848; called by muse, mutect2, varscan2
- USP38 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61024826; called by muse, mutect2, varscan2
- VAX2 | c.731del p.P244Lfs*32 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as rs782413577; called by mutect2, pindel, varscan2
- VCAM1 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780212367, COSV54117766; called by muse, mutect2, varscan2
- VCAN | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV54096915; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | catalogued as rs756863093; called by mutect2, varscan2
- VMA21 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs1464563401, COSV57755903; called by muse, mutect2, varscan2
- VRTN | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV56439224; called by muse, mutect2, varscan2
- VWA2 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53904976; called by muse, mutect2, varscan2
- WDR3 | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV62522460; called by muse, mutect2, varscan2
- WDR43 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV56097939; called by muse, mutect2, varscan2
- WDR72 | c.661T>C p.C221R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64741655; called by muse, mutect2, varscan2
- WIPF2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV60272230; called by muse, mutect2, varscan2
- XPO6 | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs750607548, COSV58963372; called by muse, mutect2, varscan2
- XRN1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs772740589, COSV53807970; called by muse, mutect2, varscan2
- XRRA1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs369302102, COSV58496163; called by muse, mutect2, varscan2
- YWHAZ | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62053411; called by muse, mutect2, varscan2
- ZBED1 | c.1771T>C p.W591R | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58130010; called by muse, mutect2, varscan2
- ZBED1 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.514); catalogued as rs973984226, COSV58130021; called by muse, mutect2, varscan2
- ZBTB11 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1447529156, COSV57246042, COSV57246512; called by muse, mutect2
- ZBTB5 | c.1556G>T p.R519M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV57038840; called by muse, mutect2, varscan2
- ZC3H18 | c.2406del p.Q804Sfs*15 | Frame Shift Del (DEL) | VAF 65/182 reads (36%) | catalogued as rs750724166; called by mutect2, pindel, varscan2
- ZCRB1 | c.419del p.K140Rfs*13 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs750821771; called by mutect2, varscan2
- ZFP36L2 | c.57_58del p.K20Ifs*63 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs1277102390; called by pindel, varscan2
- ZNF106 | c.4963G>T p.G1655C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55513703; called by muse, mutect2, varscan2
- ZNF221 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as rs148293806; called by muse, mutect2, varscan2
- ZNF239 | c.1297T>C p.C433R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60018001; called by muse, mutect2, varscan2
- ZNF296 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs752866032, COSV55514374; called by muse, mutect2, varscan2
- ZNF331 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV53474916; called by muse, mutect2, varscan2
- ZNF354A | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59982142; called by muse, mutect2, varscan2
- ZNF407 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs770394467, COSV55242870; called by muse, mutect2, varscan2
- ZNF429 | c.1477T>C p.S493P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV61914618; called by muse, mutect2, varscan2
- ZNF454 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1021248473, COSV60766845, COSV60768682; called by muse, mutect2
- ZNF462 | c.4369C>T p.Q1457* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV52930313; called by muse, mutect2, varscan2
- ZNF518A | c.57del p.D20Ifs*4 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as COSV60151560; called by mutect2, pindel, varscan2
- ZNF518B | c.1967C>T p.T656M | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372302721; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 72/186 reads (39%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF687 | c.3098G>A p.R1033H | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199981013, COSV55014969; called by muse, mutect2, varscan2
- ZNF862 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs748305753, COSV56222729; called by muse, mutect2, varscan2
- ZNFX1 | c.4987C>T p.R1663W | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs150988771; called by muse, mutect2, varscan2
- ZSCAN20 | c.1703T>C p.L568P | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63681558; called by muse, mutect2, varscan2
- ABCA7 | c.5371del p.D1791Mfs*5 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- ACAD11 | c.1645del p.I549Lfs*21 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- ACP2 | c.772+1del p.X258_splice | Splice Site (DEL) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
- ADAM28 | c.1225dup p.I409Nfs*14 | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- ADAM7 | c.1781del p.L594Yfs*29 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- AFF1 | c.1870del p.E624Kfs*22 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel, varscan2
- ANK2 | c.5190del p.G1731Vfs*7 | Frame Shift Del (DEL) | VAF 107/319 reads (34%) | called by mutect2, pindel, varscan2
- ARHGEF35 | c.1409del p.L470* | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- ASPH | c.541_543del p.Q181del | In Frame Del (DEL) | VAF 114/543 reads (21%) | called by pindel, varscan2
- ATP10A | c.4310dup p.L1437Ffs*79 | Frame Shift Ins (INS) | VAF 9/88 reads (10%) | called by mutect2, pindel, varscan2
- BBS12 | c.1680dup p.E561Rfs*11 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- BICRAL | c.2689del p.T897Qfs*8 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- CACNA1E | c.6649del p.Q2217Sfs*79 (on ENST00000367573 / NM_001205293.3; = p.Q2174Sfs*79 on NM_000721.4) | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- CASKIN1 | c.1847dup p.L618Pfs*10 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- CBFA2T3 | c.234del p.S79Afs*41 | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | called by mutect2, pindel, varscan2
- CD40 | c.682del p.H228Tfs*85 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 36/59 reads (61%) | called by mutect2, pindel, varscan2
- CIBAR2 | c.547del p.C183Vfs*4 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- CLDN19 | c.244dup p.A82Gfs*79 | Frame Shift Ins (INS) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- COPS2 | c.777del p.F259Lfs*19 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- CUEDC1 | c.91del p.Q31Rfs*57 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel
- CYYR1 | c.437dup p.P147Sfs*48 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- DAO | c.357dup p.R120Qfs*31 | Frame Shift Ins (INS) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- DENND4C | c.1935del p.F645Lfs*5 | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | called by pindel, varscan2
- DGAT1 | c.1343del p.F448Sfs*20 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, varscan2
- EHMT2 | c.46del p.E16Rfs*68 | Frame Shift Del (DEL) | VAF 52/147 reads (35%) | called by mutect2, pindel, varscan2
- EXOC8 | c.2042del p.L681Yfs*27 | Frame Shift Del (DEL) | VAF 38/115 reads (33%) | called by mutect2, pindel, varscan2
- FZR1 | c.1124del p.G375Afs*14 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.5852del p.N1951Mfs*8 | Frame Shift Del (DEL) | VAF 53/205 reads (26%) | called by mutect2, pindel, varscan2
- GPR139 | c.1034del p.N345Mfs*5 | Frame Shift Del (DEL) | VAF 50/132 reads (38%) | called by mutect2, pindel, varscan2
- GPR149 | c.1174del p.I392Sfs*21 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- GPR171 | c.64del p.Y22Ifs*2 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, varscan2
- GPSM3 | c.50del p.P17Lfs*77 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- HEY2 | c.872del p.P291Qfs*56 | Frame Shift Del (DEL) | VAF 121/338 reads (36%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.1753del p.R585Gfs*3 | Frame Shift Del (DEL) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- IGSF9 | c.1696dup p.A566Gfs*86 (on ENST00000368094 / NM_001135050.2; = p.A550Gfs*86 on NM_020789.4) | Frame Shift Ins (INS) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- KCNC4 | c.401dup p.I135Hfs*47 | Frame Shift Ins (INS) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- KCTD3 | c.133del p.S45Pfs*4 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, varscan2
- KIAA0100 | c.2658del p.F886Lfs*3 | Frame Shift Del (DEL) | VAF 82/232 reads (35%) | called by mutect2, pindel, varscan2
- KIAA1143 | c.191del p.K64Rfs*10 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- KIF20A | c.1180del p.E394Kfs*4 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- KIFC2 | c.408del p.R137Gfs*73 | Frame Shift Del (DEL) | VAF 46/215 reads (21%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.485A>C p.E162A | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.217); called by muse, mutect2
- L3MBTL2 | c.270_271del p.C90* | Frame Shift Del (DEL) | VAF 37/117 reads (32%) | called by pindel, varscan2
- LHCGR | c.1764del p.F588Lfs*14 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- LRRFIP2 | c.1459del p.I487Lfs*4 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- LTBP4 | c.2282del p.P761Hfs*50 (on ENST00000308370 / NM_001042544.1; = p.P724Hfs*50 on NM_003573.2) | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- MAGI3 | c.1877del p.N626Mfs*5 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- MAP7 | c.1339_1356del p.P447_A452del | In Frame Del (DEL) | VAF 5/26 reads (19%) | called by pindel, varscan2
- MCC | c.152del p.K51Rfs*14 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- MICAL3 | c.5116del p.R1706Afs*24 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- MUC17 | c.1957_1959del p.P653del | In Frame Del (DEL) | VAF 103/342 reads (30%) | called by mutect2, pindel, varscan2
- MYH9 | c.443dup p.H149Sfs*27 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- NFATC4 | c.1756_1765del p.P586Rfs*10 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel
- NLRP3 | c.1358del p.G453Efs*49 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- NRDC | c.616del p.T206Lfs*17 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, varscan2
- OSBPL9 | c.1355del p.K452Sfs*27 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- PCNX2 | c.3207del p.K1069Nfs*19 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- PDS5B | c.3939del p.G1314Efs*80 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- PMCH | c.203del p.N68Mfs*7 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PSMG2 | c.448del p.S150Vfs*6 | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | called by mutect2, pindel, varscan2
- PTCH2 | c.3545dup p.W1183Lfs*7 | Frame Shift Ins (INS) | VAF 37/93 reads (40%) | called by mutect2, pindel, varscan2
- PVR | c.596_597del p.T199Sfs*30 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by pindel, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | called by mutect2, pindel, varscan2
- RNF128 | c.594del p.K198Nfs*6 (on ENST00000255499 / NM_194463.2; = p.K172Nfs*6 on NM_024539.3) | Frame Shift Del (DEL) | VAF 40/105 reads (38%) | called by mutect2, pindel, varscan2
- RPRD2 | c.788del p.N263Tfs*5 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- RYR1 | c.14292dup p.L4765Afs*106 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- SALL2 | c.1577del p.N526Tfs*25 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- SEMA4B | c.909_912del p.F303Lfs*25 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- SH3PXD2A | c.328del p.H110Tfs*47 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel
- SIPA1L1 | c.4467dup p.P1490Tfs*23 | Frame Shift Ins (INS) | VAF 38/118 reads (32%) | called by mutect2, pindel, varscan2
- SLC36A4 | c.1080dup p.V361Cfs*25 | Frame Shift Ins (INS) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- SLCO5A1 | c.2436del p.I814Sfs*16 | Frame Shift Del (DEL) | VAF 33/175 reads (19%) | called by mutect2, pindel, varscan2
- SP100 | c.893del p.K298Rfs*26 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- SRCAP | c.4182del p.L1395* | Frame Shift Del (DEL) | VAF 40/135 reads (30%) | called by mutect2, pindel, varscan2
- TAF6 | c.1293_1294del p.A432Sfs*11 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | called by pindel, varscan2
- TDRD3 | c.755_756dup p.R253Gfs*3 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- TEP1 | c.3504del p.Q1169Sfs*28 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- TESK1 | c.1107del p.N370Tfs*6 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | called by mutect2, pindel, varscan2
- TLR6 | c.121del p.R41Efs*12 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | called by mutect2, pindel, varscan2
- TMEM236 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNRC6C | c.1969dup p.E657Gfs*13 | Frame Shift Ins (INS) | VAF 9/23 reads (39%) | called by mutect2, varscan2
- TRANK1 | c.5531del p.K1844Sfs*6 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- TRAP1 | c.1296del p.D433Mfs*21 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- TRIO | c.3657del p.K1219Nfs*43 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | called by mutect2, pindel, varscan2
- TTN | c.100830del p.K33610Nfs*3 (on ENST00000591111; = p.K26186Nfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- UBQLN2 | c.1574del p.P525Lfs*71 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- UHRF1BP1L | c.3902del p.L1301Wfs*9 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- VPS13B | c.5737del p.I1913* | Frame Shift Del (DEL) | VAF 24/163 reads (15%) | called by mutect2, pindel, varscan2
- WASHC2A | c.3834A>C p.K1278N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED4 | c.1972del p.I658Sfs*5 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | called by mutect2, varscan2
- ZC3H13 | c.2282_2283dup p.R762Sfs*104 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- ACVR1C | c.1416C>T p.R472= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV54643723; called by muse, mutect2, varscan2
- ADAMTS19 | c.648G>A p.P216= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV50732191; called by muse, mutect2, varscan2
- AHNAK | c.12321T>C p.G4107= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV57203613; called by muse, mutect2, varscan2
- AHNAK2 | c.9795C>T p.P3265= | Silent (SNP) | VAF 121/272 reads (44%) | catalogued as rs755891092, COSV60907891; called by muse, mutect2, varscan2
- AKAP9 | c.3699C>T p.Y1233= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV62338705; called by muse, mutect2, varscan2
- ALPP | c.1317C>T p.P439= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1424088674, COSV67395644; called by muse, mutect2, varscan2
- ANKRD50 | c.2181C>T p.H727= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs751606786, COSV72385045; called by muse, mutect2, varscan2
- AP1B1 | c.1083C>T p.Y361= | Silent (SNP) | VAF 80/227 reads (35%) | catalogued as rs371955281, COSV58014540; called by muse, mutect2, varscan2
- ARHGEF40 | c.1284C>T p.C428= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV53878164; called by muse, mutect2, varscan2
- ARIH2 | c.525C>T p.D175= | Silent (SNP) | VAF 48/173 reads (28%) | catalogued as rs746385013, COSV62703860; called by muse, mutect2, varscan2
- ART3 | c.609C>T p.I203= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1320935709, COSV61913087; called by muse, mutect2, varscan2
- ATF6 | c.1248G>A p.R416= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV63405924; called by muse, mutect2, varscan2
- ATP10D | c.624G>A p.E208= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV56703881; called by muse, mutect2, varscan2
- ATP2A2 | c.1842G>A p.R614= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as COSV57875035; called by muse, mutect2, varscan2
- ATP2B4 | c.1380C>T p.T460= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs762715419, COSV58174334; called by muse, mutect2, varscan2
- ATXN7L3 | c.159G>A p.T53= | Silent (SNP) | VAF 62/162 reads (38%) | catalogued as rs142032853; called by muse, mutect2, varscan2
- B3GAT1 | c.207C>T p.T69= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs373742481, COSV56994993; called by muse, mutect2, varscan2
- B4GALT5 | c.1101C>T p.Y367= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs529151995, COSV65492668, COSV65494809; called by muse, mutect2, varscan2
- BAG4 | c.207C>T p.G69= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV54859195; called by muse, mutect2, varscan2
- BCAM | c.1026C>T p.Y342= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs770541247, COSV54300585; called by muse, mutect2, varscan2
- BEST3 | c.711C>T p.T237= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV58298794; called by muse, mutect2, varscan2
- BPHL | c.720C>T p.H240= | Silent (SNP) | VAF 79/248 reads (32%) | catalogued as rs553521784, COSV66743002; called by muse, mutect2, varscan2
- C11orf94 | c.153G>A p.Q51= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as rs1284309726, COSV53796648; called by muse, mutect2, varscan2
- C8orf33 | c.459C>A p.P153= | Silent (SNP) | VAF 48/181 reads (27%) | catalogued as COSV58895282; called by muse, mutect2, varscan2
- CASZ1 | c.4665C>T p.A1555= | Silent (SNP) | VAF 43/50 reads (86%) | catalogued as COSV65456072; called by muse, mutect2, varscan2
- CASZ1 | c.57C>T p.P19= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV59732056, COSV59740313; called by muse, mutect2, varscan2
- CCNF | c.684C>T p.S228= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1280025116, COSV53537793; called by muse, mutect2, varscan2
- CDH7 | c.1746G>A p.V582= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV59881570; called by muse, mutect2, varscan2
- CDHR3 | c.561C>T p.G187= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs892144173, COSV58413739; called by muse, mutect2, varscan2
- CDKN1A | c.381T>C p.A127= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs1413611071, COSV55186983; called by muse, mutect2, varscan2
- CEP97 | c.1428T>C p.N476= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- CHD2 | c.3360G>A p.P1120= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1191117970, COSV67706699; called by muse, mutect2, varscan2
- CLIP2 | c.1209T>C p.H403= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV56274422; called by muse, mutect2, varscan2
- CNGA1 | c.102A>G p.A34= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV62052947; called by muse, mutect2, varscan2
- CNTFR | c.945T>C p.A315= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs768332669, COSV63633108; called by muse, mutect2, varscan2
- COL11A1 | c.4530C>T p.G1510= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs775945644, COSV62172958; called by muse, mutect2, varscan2
- CRYL1 | c.582T>C p.V194= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV53416274; called by muse, mutect2, varscan2
- CSF2RA | c.552A>G p.S184= | Silent (SNP) | VAF 69/174 reads (40%) | catalogued as rs144461474, COSV62623506; called by muse, mutect2, varscan2
- CSMD3 | c.9051T>C p.V3017= (on ENST00000297405 / NM_001363185.1; = p.V2848= on NM_052900.3) | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV52103399; called by muse, mutect2, varscan2
- CTSG | c.688A>C p.R230= | Silent (SNP) | VAF 89/206 reads (43%) | catalogued as COSV53534611; called by muse, mutect2, varscan2
- DAGLA | c.3045G>A p.A1015= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs749910641, COSV57193985; called by muse, mutect2, varscan2
- DBT | c.1110C>T p.I370= | Silent (SNP) | VAF 77/217 reads (35%) | catalogued as rs771962372, COSV64494937; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDI1 | c.1053C>T p.I351= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1226735014, COSV56368599, COSV56374872; called by muse, mutect2, varscan2
- DIP2A | c.1200G>A p.A400= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs368091015; called by muse, mutect2, varscan2
- DIPK2B | c.247C>T p.L83= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV65005008; called by muse, mutect2
- DLC1 | c.2085C>T p.S695= (on ENST00000276297 / NM_001348081.2; = p.S258= on NM_006094.5) | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as rs148579135; called by muse, mutect2, varscan2
- DMXL2 | c.3363A>G p.Q1121= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs757811133, COSV51840807; called by muse, mutect2, varscan2
- DNAL4 | c.159C>T p.A53= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1395440948, COSV53308451; called by muse, mutect2
- DOCK11 | c.3804A>G p.V1268= | Silent (SNP) | VAF 72/172 reads (42%) | catalogued as COSV52233671; called by muse, mutect2, varscan2
- DOP1B | c.519G>A p.S173= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs143348611; called by muse, mutect2, varscan2
- DOP1B | c.2445C>A p.S815= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV101215835, COSV67692096; called by muse, mutect2, varscan2
- DPP8 | c.1377T>C p.S459= (on ENST00000341861 / NM_001320875.2; = p.S443= on NM_017743.6) | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV55676001; called by muse, mutect2, varscan2
- DUOX1 | c.1119A>G p.P373= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1242842651, COSV58477349; called by muse, mutect2, varscan2
- DUS2 | c.1068T>C p.A356= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs770006864, COSV62707854; called by muse, mutect2, varscan2
- EBF3 | c.1242C>T p.S414= (on ENST00000355311 / NM_001375392.1; = p.S405= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/267 reads (28%) | catalogued as rs771823461, COSV62471852, COSV62477068; called by muse, mutect2, varscan2
- EFHC2 | c.2007T>G p.P669= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV59092284; called by muse, mutect2, varscan2
- ELOA2 | c.1167C>T p.Y389= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs766776711, COSV55293548; called by muse, mutect2, varscan2
- EMC9 | c.174C>T p.V58= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV52823300; called by muse, mutect2, varscan2
- ESYT1 | c.1098C>A p.T366= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV57271606; called by muse, mutect2, varscan2
171 further variants in this file (0 protein-altering or splice-affecting, 153 silent, 18 other) are not listed here.
